Gene-level copy-number profile of tumor specimen TCGA-MV-A51V-01A from TCGA case TCGA-MV-A51V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.1 years (27,430 days).
Specimen TCGA-MV-A51V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.21cc6d1e-53c9-4860-829f-4dc994608288.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MV-A51V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94736c05-a0e8-45a4-8ba7-502efe2b10e4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 590; copy number 3: 4,592; copy number 4: 16,794; copy number 5: 16,522; copy number 6: 9,675; copy number 7: 6,445; copy number 8: 1,378; copy number 9: 1,091; copy number 10: 1,105; copy number 11: 566; copy number 12: 227; copy number 13: 475; copy number 14: 177; copy number 15: 17; copy number 16: 73; copy number 18: 40; copy number 20: 35; copy number 23: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MV-A51V-01A-11D-A26L-01): tumor purity 0.75, ploidy 5.35, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,806 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,885,994–47,498,341, 464 genes, copy number 10–13 (broad region; genes not listed).
- chr1:48,172,972–66,374,579, 351 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr1:150,600,539–152,042,774, 86 genes, copy number 13 (within-gene range 7–13) (broad region; genes not listed).
- chr1:153,533,603–179,576,349, 768 genes, copy number 10–14 (broad region; genes not listed).
- chr2:53,532,672–53,860,160, 1 gene, copy number 10 (within-gene range 7–10): ASB3.
- chr2:53,767,804–53,970,993, 5 genes, copy number 10: CHAC2, ERLEC1, MIR3682, GPR75, PSME4.
- chr3:12,004,388–13,937,477, 35 genes, copy number 20 (within-gene range 6–20): SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1.
- chr4:72,807,267–76,898,144, 95 genes, copy number 11–16 (broad region; genes not listed).
- chr4:76,958,860–76,959,169, 1 gene, copy number 16: TXNP6.
- chr4:84,583,127–89,999,409, 91 genes, copy number 9–14 (broad region; genes not listed).
- chr4:90,370,123–90,370,427, 1 gene, copy number 9: RN7SKP248.
- chr4:95,549,129–96,818,864, 8 genes, copy number 11 (within-gene range 5–11): AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28.
- chr6:120,462,511–122,859,988, 35 genes, copy number 9: AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2.
- chr7:16,791,811–20,777,038, 50 genes, copy number 18–23 (within-gene range 6–23): AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1.
- chr7:34,658,218–37,951,936, 64 genes, copy number 16 (within-gene range 7–16) (broad region; genes not listed).
- chr7:78,017,055–79,453,667, 1 gene, copy number 9 (within-gene range 8–9): MAGI2.
- chr7:78,347,142–80,391,474, 22 genes, copy number 9 (within-gene range 8–9): RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P.
- chr11:55,262,155–57,056,132, 128 genes, copy number 9 (broad region; genes not listed).
- chr14:49,927,571–50,231,578, 8 genes, copy number 9 (within-gene range 5–9): LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2.
- chr17:37,798,894–42,121,367, 237 genes, copy number 9 (broad region; genes not listed).
- chr17:42,122,804–42,123,352, 1 gene, copy number 9: HSPB9.
- chr17:48,762,235–49,230,787, 26 genes, copy number 12: TTLL6, RN7SL125P, CALCOCO2, SUMO2P17, AC068531.1, AC068531.2, ATP5MC1, AC091133.6, UBE2Z, SNF8, AC091133.1, RNU1-42P, AC091133.2, GIP, AC091133.3, IGF2BP1, AC091133.4, Metazoa_SRP, RNU6-826P, AC091133.5, B4GALNT2P1, B4GALNT2, AC069454.1, GNGT2, ABI3, PHOSPHO1.
- chr17:59,707,192–83,095,122, 770 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 10–15 (broad region; genes not listed).
- chr20:31,274,170–35,769,867, 180 genes, copy number 9 (broad region; genes not listed).
- chr20:35,850,674–35,853,364, 2 genes, copy number 9: COX7BP2, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
